Somatic mutation profile of tumor specimen BA3196D (aliquot aq-BA3196D) from BEATAML1.0 case 2721, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 76.1 years (27,803 days).
Specimen BA3196D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a501fcd-d31f-4e02-bafd-56304d836297.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3102D (Solid Tissue Normal), aliquot aq-BA3102D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5156df33-d4f7-4dbe-87c6-89db688c729c

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC151 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs529248956, COSV100710483; called by muse, mutect2, varscan2
- DNAH9 | c.7408C>T p.R2470W | Missense Mutation (SNP) | VAF 79/182 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs777792290, COSV52339093; called by muse, mutect2, varscan2
- GDF10 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs985793502; called by muse, varscan2
- PCDHA5 | c.1621G>A p.V541M | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.104); catalogued as rs17844295, COSV100972090; called by muse, mutect2, varscan2
- STYXL2 | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 46/204 reads (23%) | called by muse, mutect2, varscan2
- WT1 | c.612_627del p.P205Afs*81 | Frame Shift Del (DEL) | VAF 23/108 reads (21%) | called by mutect2, pindel, varscan2
